CCDI case PBCMWP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/279f0cec-86c4-4059-a21a-7f19d7077c5f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 3.4 years (1,243 days).

Biospecimens (3 samples)
- Sample 0DVR5S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVR6Y: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVR7V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
